TCGA case TCGA-YS-AA4M — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2dd1ecd8-a8d8-4a6a-8cf2-e847557ab04c

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 66 years; Vital status: Dead; Days to death: 84 days.

Diagnoses (2)
1. Mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9050/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 66.2 years (24,176 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Mesothelioma, malignant), site: Bone, NOS. Age at diagnosis: 65.8 years (24,045 days); Days to diagnosis: -131 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day -131 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: -131 days.
- Days to follow up: 84 days; Disease response: With Tumor.
- ECOG performance status: 2; Timepoint: Preoperative.

Exposures
- Occupation type: Mixed Crop and Animal Producers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YS-AA4M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 30 mg.
  Slide TCGA-YS-AA4M-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-YS-AA4M-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YS-AA4M-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; Primary occupation: Other, please specify; Occupation primary: Farmer.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Diffuse malignant mesothelioma - NOS.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 84 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 84 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), time not recorded.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YS-AA4M-01A-11D-A39Q-01): tumor purity 0.17, ploidy 2.01, whole-genome doublings 0.
